Somatic mutation profile of tumor specimen TCGA-IB-A5SS-01A (aliquot TCGA-IB-A5SS-01A-11D-A32N-08) from TCGA case TCGA-IB-A5SS, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 64.2 years (23,431 days).
Specimen TCGA-IB-A5SS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38476d06-b206-44d1-a915-765aab0c8b2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-A5SS-10A (Blood Derived Normal), aliquot TCGA-IB-A5SS-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3260f16d-8574-4e16-ac2e-c52d8dcbbcbe

The open-access MAF lists 38 somatic variants for this specimen: 32 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 5, Nonsense Mutation 3, Frame Shift Del 3, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 14/92 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 45/131 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARMC7 | c.501C>A p.F167L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99822745; called by muse, mutect2, varscan2
- ASTN1 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763391667, COSV56064196; called by muse, mutect2, varscan2
- CACNA1I | c.1225C>T p.H409Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100361565; called by muse, mutect2
- CNTN3 | c.1760C>A p.S587* | Nonsense Mutation (SNP) | VAF 27/113 reads (24%) | catalogued as COSV99726120; called by muse, mutect2, varscan2
- CNTN3 | c.1759T>A p.S587T | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV99726122; called by muse, mutect2, varscan2
- DHRS2 | c.718C>A p.H240N | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as COSV51633454, COSV99160461; called by muse, mutect2, varscan2
- GADL1 | c.1050T>A p.S350= | Splice Region (SNP) | VAF 36/175 reads (21%) | catalogued as COSV99245099; called by muse, mutect2, varscan2
- HLX | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV100854630; called by muse, mutect2, varscan2
- HSPA5 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99413195, COSV99413643; called by muse, mutect2, varscan2
- ICE2 | c.737T>C p.I246T | Missense Mutation (SNP) | VAF 86/353 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1194054579, COSV99831848; called by muse, mutect2, varscan2
- IFNA10 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 124/776 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV99497604; called by muse, varscan2
- KDM6B | c.2438G>A p.G813E | Missense Mutation (SNP) | VAF 110/376 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.591); catalogued as rs1276628632, COSV99642329; called by muse, mutect2, varscan2
- KIR3DL1 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 126/390 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100428936; called by muse, mutect2, varscan2
- LRIT1 | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.108); catalogued as rs761349415, COSV64512167; called by muse, mutect2, varscan2
- LSR | c.877G>A p.V293I (on ENST00000361790; = p.V274I on NM_015925.6) | Missense Mutation (SNP) | VAF 79/459 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.344); catalogued as rs540686530, COSV100670654, COSV61555847; called by muse, mutect2, varscan2
- LTBP4 | c.3264C>G p.H1088Q (on ENST00000308370 / NM_001042544.1; = p.H1051Q on NM_003573.2) | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99199630; called by muse, mutect2, varscan2
- MC5R | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs758915138, COSV61256124; called by muse, mutect2, varscan2
- NOS1 | c.3802C>T p.R1268W | Missense Mutation (SNP) | VAF 199/612 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57616138; called by muse, mutect2, varscan2
- PCDHA4 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV100793461; called by muse, mutect2, varscan2
- RUSC2 | c.2547T>A p.H849Q | Missense Mutation (SNP) | VAF 92/362 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.643); catalogued as COSV100770901; called by muse, mutect2, varscan2
- SCNN1G | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 90/376 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV100264516; called by muse, mutect2, varscan2
- SGCZ | c.933G>A p.W311* | Nonsense Mutation (SNP) | VAF 82/434 reads (19%) | catalogued as COSV66039620, COSV66043270; called by muse, mutect2, varscan2
- SORL1 | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 88/359 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.185); catalogued as COSV99495532; called by muse, mutect2, varscan2
- TMEM161B | c.620G>T p.S207I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV99680840; called by muse, mutect2
- TSC2 | c.4766C>T p.P1589L | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373635516; called by muse, mutect2, varscan2
- ZCCHC7 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.031); catalogued as rs774347475, COSV100383577; called by muse, mutect2, varscan2
- LRIG3 | c.1274del p.L425Yfs*9 | Frame Shift Del (DEL) | VAF 37/197 reads (19%) | called by mutect2, pindel, varscan2
- RBM10 | c.822del p.Q274Hfs*34 | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | called by mutect2, pindel*, varscan2*
- SMAD4 | c.1520_1521del p.K507Rfs*19 | Frame Shift Del (DEL) | VAF 51/228 reads (22%) | called by mutect2, pindel, varscan2
- DNAH11 | c.4125C>A p.R1375= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as rs570983771, COSV100180953, COSV60972118; ClinVar: likely benign; called by muse, mutect2, varscan2
- LCN9 | c.426C>T p.C142= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs759766790, COSV52990544; called by muse, mutect2, varscan2
- PCDH1 | c.2016C>T p.S672= | Silent (SNP) | VAF 77/330 reads (23%) | catalogued as rs149691852, COSV99747001; called by muse, mutect2, varscan2
- RASGEF1C | c.1281C>T p.T427= | Silent (SNP) | VAF 46/215 reads (21%) | catalogued as rs761597124, COSV100746401; called by muse, mutect2, varscan2
- SLC45A2 | c.168G>C p.V56= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99673173; called by muse, mutect2, varscan2
- C9orf106 | n.561C>A | RNA (SNP) | VAF 46/199 reads (23%) | catalogued as rs1267192652; called by muse, mutect2, varscan2
